Surgical pathology report (de-identified scan), TCGA case TCGA-KU-A6H8, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Hartford, specimen TCGA-KU-A6H8-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

DATE RECEIVED:
DATE REPORTED:

CC:

DIAGNOSIS

**1. TONGUE, RIGHT POSTERIOR LATERAL, PARTIAL GLOSSECTOMY:
INVASIVE SQUAMOUS CELL CARCINOMA**

Tumor type:	In situ and invasive Squamous cell carcinoma
Histologic grade:	Moderately to poorly differentiated
Tumor size:	4 cm
Tumor location:	Right posterior lateral
Midline extension:	Tumor does not extend across midline
Level of invasion:	Skeletal muscle of the tongue
Vascular invasion:	Present
Perineural invasion:	Present
Margins:	Negative; 0.5 mm to deep margin; 1 mm to superior (medial) margin
Lymph nodes:	Margin re-excisions negative (see specimens 2, 3, 5, 6, 7). 2 out of 16 lymph nodes positive for carcinoma with extension into hilar fat- largest metastasis measuring 4 cm (2/16). Level 1B: two negative lymph nodes (0/2) Level 2A: one out of three positive lymph nodes (1/3) Level 2B: three negative lymph nodes (0/3) Level 3: One of eight lymph nodes with metastatic carcinoma (1/8)
Other findings:	Tumor necrosis
AJCC stage:	Stage IVA (pT2 pN2b)

ICD-O-3

Carcinoma, squamous
cell NOS 8070/3

Site Tongue NOS C02.9

QW 6/17/13

2. TONGUE, POSTERIOR/SUPERIOR MARGIN, BIOPSY: MILD SQUAMOUS ATYPIA; NEGATIVE FOR IN SITU AND INVASIVE CARCINOMA.

3. TONGUE, POSTERIOR MARGIN, BIOPSY: MILD SQUAMOUS ATYPIA; NEGATIVE FOR IN SITU AND INVASIVE CARCINOMA.

4. MOUTH, FLOOR MARGIN, BIOPSY: MILD SQUAMOUS ATYPIA; NEGATIVE FOR IN SITU AND INVASIVE CARCINOMA.

5. TONGUE, ANTERIOR MARGIN, BIOPSY: MILD SQUAMOUS ATYPIA; NEGATIVE FOR IN SITU AND INVASIVE CARCINOMA.

6. TONGUE, ANTERIOR/SUPERIOR MARGIN, BIOPSY: MILD SQUAMOUS ATYPIA; NEGATIVE FOR IN SITU AND INVASIVE CARCINOMA.

[page 2 of 3]
Surgical Pathology Report

7. TONGUE, DEEP POSTERIOR MARGIN, BIOPSY: MILD SQUAMOUS ATYPIA; NEGATIVE FOR IN SITU AND INVASIVE CARCINOMA.

8. RIGHT NECK, LEVEL IB, DISSECTION: SUBMANDIBULAR GLAND AND TWO LYMPH NODES NEGATIVE FOR INVASIVE CARCINOMA (0/2).

**9. RIGHT NECK, LEVEL 2A AND 3, DISSECTION:
LEVEL 2A: ONE OF THREE LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA WITH EXTENSION INTO HILAR FAT (1/3).**

LEVEL 3: ONE OF EIGHT LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (1/8).

10. RIGHT LEVEL 2B: THREE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/3).

Electronically Signed Out

COMMENT

88307x3, 88305x7, 88331x7

Clinical Diagnosis and History:

Right tongue cancer

Tissue(s) Submitted:

- 1: RIGHT POSTERIOR LATERAL TONGUE STITCH ANTERIOR
- 2: POSTERIOR/SUPERIOR CLIP ANTERIOR
- 3: POSTERIOR MARGIN
- 4: FLOOR OF MOUTH MARGIN CLIP ANTERIOR
- 5: ANTERIOR MARGIN CLIP DORSAL
- 6: ANTERIOR/SUPERIOR CLIP ANTERIOR
- 7: DEEP POSTERIOR
- 8: RIGHT NECK DISSECTION LEVEL IB
- 9: RIGHT LEVEL 2A AND3, STITCH IN LEVEL 2A
- 10: RIGHT LEVEL 2B

Gross Description:

Specimen #1 is received fresh, labeled with the patient's name, designated right posterior lateral tongue (stitch anterior) and consists of a 4.5 x 3 cm pink-red segment of tongue excised to a depth of 0.8 cm. The tongue surface displays a 2 x 1 cm pink-red area of ulceration located 0.5 cm from the inferior/deep margin. The superior deep margin is blue, the inferior deep margin is black, and the specimen is serially sectioned from anterior to posterior to reveal tan-white, firm mass extending to within 0.1 cm of the central inked margin. A representative section is submitted for frozen section and the entire specimen is submitted for permanent sections.

Summary of sections:

- 1AFS: frozen section remnant mass to deep
1B: anterior perpendicular margin
1C-1H: central sections from anterior to posterior
1I: posterior perpendicular margin.

Specimen #2 is received fresh for intraoperative consultation, labeled with the patient's name, designated posterior/superior, clip anterior and consists of a 3.7 x 0.5 x 0.5 cm tan-pink tissue, which is entirely submitted for frozen section labeled 2AFS.

Specimen #3 is received fresh for intraoperative consultation, labeled with the patient's name, designated posterior margin and consists of a 1.5 x 0.8 x 0.3 cm tan-pink tissue which is submitted in toto for frozen section labeled 3AFS.

[page 3 of 3]
Surgical Pathology Report

Specimen #4 is received fresh for intraoperative consultation, labeled with the patient's name, designated floor of mouth margin (clip anterior) and consists of a 3.4 x 0.2 x 0.3 cm tan-pink tissue which is submitted in toto for frozen section labeled 4AFS.

Specimen #5 is received in formalin, labeled with the patient's name, designated anterior margin (clip dorsal) and consists of a 3.5 cm tan-pink tissue which is submitted in toto for frozen section labeled 5AFS.

Specimen #6 is received fresh for intraoperative consultation, labeled with the patient's name, designated anterior/superior (clip anterior) and consists of a 3.5 cm tan-pink tissue which is submitted in toto for frozen section labeled 6AFS.

Specimen #7 is received fresh for intraoperative consultation, labeled with the patient's name, designated deep posterior and consists of a 0.8 cm tan-pink tissue, which is submitted in toto labeled 7AFS.

Specimen #8 is received in formalin, labeled with the patient's name, designated right neck dissection level 1B and consists of a 5.5 x 3.2 x 1.8 cm tan-yellow, lobulated submandibular gland with attached adipose tissue to include two possible lymph nodes measuring 1 and 2 cm. Representative sections are submitted to include all possible lymph nodes.

Summary of sections:

8A-8B: representative submandibular gland
8C-8D: one lymph node, bisected per cassette.

Specimen #9 is received in formalin, labeled with the patient's name, designated right level 2A and 3 (stitch in level 2A) and consists of an 8 x 6 x 2 cm irregular tan-pink nodular fibrous tissue. A skeletal muscle and internal jugular vein are not identified. Sectioning reveals multiple possible lymph nodes ranging from 0.3 cm to 4 cm. The largest lymph node displays tan-white, cystic and grossly positive. The specimen is entirely submitted.

Summary of sections:

9A-9D: level 2A largest lymph node quadrisectioned
9E-9H: level 2A remaining soft tissue
9I: level 3 three possible lymph nodes intact
9J: level 3 one lymph node bisected
9K-9L: one lymph node serially sectioned
9M-9N: level 3 one lymph node serially sectioned
9O-9P: level 3 one lymph node serially sectioned
1Q-1S: level 3 one lymph node serially sectioned.

Specimen #10 is received in formalin, labeled with the patient's name, designated right level 2B and consists of a 2.5 cm tan-yellow, ovoid unoriented tissue which is serially sectioned and entirely submitted labeled 10A-10D.

Intraoperative Consult Diagnosis

1A/FSDX: INVASIVE SQUAMOUS CELL CARCINOMA FOCALLY ~1MM FROM MEDIAL/ SUPERIOR MARGIN.
2A/FSDX: POSTERIOR-SUPERIOR MARGIN NEGATIVE.
3A/FSDX: POSTERIOR MARGIN NEGATIVE.
4A/FSDX: FLOOR OF MOUTH MARGIN NEGATIVE.
5A/FSDX: ANTERIOR MARGIN NEGATIVE.
6A/FSDX: ANTERIOR-SUPERIOR MARGIN NEGATIVE.
7A/FSDX: DEEP MARGIN NEGATIVE.

Criteria	hw 5/24/13	Yes	No

Source: NCI Genomic Data Commons file 3a780f14-c9e1-42af-a783-1f17891ed46f (TCGA-KU-A6H8.36CAD6F3-4C31-42BC-AC81-8881D7FA4D89.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).